Somatic mutation profile of tumor specimen TCGA-DC-6682-01A (aliquot TCGA-DC-6682-01A-11D-1826-10) from TCGA case TCGA-DC-6682, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.7 years (21,062 days).
Specimen TCGA-DC-6682-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6fc1a4b-e7fb-40cf-8bff-88b21c0b2802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6682-10A (Blood Derived Normal), aliquot TCGA-DC-6682-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e6fe5ab-fd0d-4bf3-9dfb-c4d217f2de0f

The open-access MAF lists 156 somatic variants for this specimen: 106 protein-altering or splice-affecting, 46 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 46, Nonsense Mutation 8, Frame Shift Ins 4, Splice Site 2, Frame Shift Del 2, Intron 2, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 74/109 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/131 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs190137939, COSV54692960; called by mutect2, varscan2
- ABCC6 | c.2915C>T p.A972V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as rs768619900, COSV52741318; called by muse, mutect2, varscan2
- AC092143.1 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs587784506, COSV59247047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADRB1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65167632; called by muse, mutect2, varscan2
- ANKRD11 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs779534634, COSV56355101; called by muse, mutect2, varscan2
- APC | c.1569del p.G524Afs*3 | Frame Shift Del (DEL) | VAF 52/139 reads (37%) | catalogued as COSV99967016; called by mutect2, pindel, varscan2
- AQP4 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV101270560, COSV101270572; called by muse, mutect2, varscan2
- ARPC5L | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV52346396; called by muse, mutect2
- ARPP21 | c.2116A>G p.N706D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV51792339; called by muse, mutect2, varscan2
- ASIC1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99948293; called by muse, mutect2, varscan2
- ATAD3B | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as rs144497634; called by muse, mutect2, varscan2
- BAHD1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1034959264, COSV69083634; called by muse, mutect2, varscan2
- BPIFB2 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV50063124; called by muse, mutect2, varscan2
- BTBD17 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV64729864; called by muse, mutect2, varscan2
- CCNDBP1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV55746348; called by muse, mutect2, varscan2
- CD180 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99842445; called by muse, mutect2, varscan2
- CFAP57 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV100994136; called by muse, mutect2
- CHRM3 | c.1700dup p.R568Efs*26 | Frame Shift Ins (INS) | VAF 17/52 reads (33%) | catalogued as rs751548647; called by mutect2, varscan2
- CLVS1 | c.798T>G p.F266L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV57970732; called by muse, mutect2, varscan2
- CNBD1 | c.1025A>G p.K342R | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as COSV73072426, COSV73075776; called by muse, mutect2, varscan2
- CNTLN | c.3467G>C p.R1156P | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52066609; called by muse, mutect2, varscan2
- COL24A1 | c.4728C>G p.F1576L | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as COSV65302060; called by muse, mutect2, varscan2
- CTNNB1 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62720176; called by muse, mutect2, varscan2
- DNAJC21 | c.1142+1G>A p.X381_splice | Splice Site (SNP) | VAF 22/200 reads (11%) | catalogued as COSV57759225; called by muse, mutect2, varscan2
- DPYD | c.2600G>T p.R867L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64591144; called by muse, mutect2, varscan2
- DYNC1H1 | c.6223C>G p.L2075V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1356421450, COSV64134449; called by muse, mutect2, varscan2
- EP300 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV54326708; called by muse, mutect2, varscan2
- EPB41L4B | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as rs201636849, COSV63124046; called by muse, mutect2, varscan2
- FAM126A | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV69016694; called by muse, mutect2, varscan2
- FAT4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs770591201, COSV101272915; called by muse, varscan2
- FBXL19 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100591020; called by muse, mutect2, varscan2
- FLG | c.6570C>A p.S2190R | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1476114093, COSV64236652; called by muse, mutect2, varscan2
- FLNC | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs767740333, COSV57950363, COSV57951627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYB1 | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV60941138, COSV60950557; called by muse, mutect2, varscan2
- GALNT5 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV52035871; called by muse, mutect2, varscan2
- GASK1B | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56704574; called by muse, mutect2, varscan2
- HEBP1 | c.423A>C p.E141D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); catalogued as COSV50009302; called by muse, mutect2, varscan2
- HECW2 | c.400+1G>A p.X134_splice | Splice Site (SNP) | VAF 6/102 reads (6%) | catalogued as rs1217846951, COSV53653908, COSV53670876; called by muse, mutect2
- HIRA | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54272154; called by muse, mutect2, varscan2
- IGF2BP1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as rs746549698, COSV51729241; called by muse, mutect2, varscan2
- IL18BP | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs768554589, COSV52619835; called by muse, mutect2, varscan2
- INTS1 | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs543463656, COSV67176378; called by muse, mutect2, varscan2
- KCND3 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1349469134, COSV56174228, COSV56187861; called by muse, mutect2, varscan2
- KCNK15 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV65719123; called by muse, mutect2, varscan2
- KMT2D | c.10906C>T p.L3636F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV56411830; called by muse, mutect2, varscan2
- KRT73 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs778008682, COSV59837922; called by muse, mutect2, varscan2
- KRTAP21-2 | c.133A>C p.T45P | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.151); catalogued as COSV100441302, COSV61683814; called by muse, mutect2
- KRTAP5-8 | c.486C>A p.C162* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV68324414, COSV68324497; called by muse, mutect2, varscan2
- LTK | c.2075del p.P692Qfs*65 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs1292224855; called by mutect2, pindel, varscan2
- MAP3K11 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV58418330; called by muse, mutect2, varscan2
- MYOM1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1355025966, COSV55285716; called by muse, mutect2, varscan2
- NCAPH2 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV53316156; called by muse, mutect2, varscan2
- NDUFA8 | c.36G>T p.E12D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65648489; called by muse, mutect2, varscan2
- NIBAN3 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs1001107332, COSV56305508; called by muse, mutect2, varscan2
- NINL | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs757912343, COSV53998713; called by muse, mutect2, varscan2
- NLN | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763794414, COSV101114522; called by muse, mutect2, varscan2
- NOVA1 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.948); catalogued as COSV57472469; called by muse, mutect2, varscan2
- NR1D1 | c.1694C>T p.T565M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201684407, COSV52840763; called by muse, mutect2, varscan2
- NSMAF | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV50683885; called by muse, mutect2, varscan2
- OR2M3 | c.490T>A p.F164I | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV71758866, COSV71759237; called by muse, mutect2
- OR5P2 | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs764331597, COSV61489936; called by muse, mutect2, varscan2
- OR8U1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541503390, COSV56414090; called by muse, mutect2, varscan2
- OTOP1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs553397205, COSV56390800; called by muse, mutect2, varscan2
- OXSM | c.533_534insG p.F178Lfs*5 | Frame Shift Ins (INS) | VAF 13/58 reads (22%) | catalogued as COSV55000792; called by mutect2, pindel, varscan2
- PCSK1 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs772483031, COSV60733792; called by muse, mutect2, varscan2
- PDE8B | c.588C>A p.C196* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV53732349; called by muse, mutect2, varscan2
- PFKP | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs777816568, COSV56526104, COSV56535389; called by muse, mutect2, varscan2
- PLCXD2 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV67338544; called by muse, mutect2, varscan2
- PNMA8B | c.1367C>A p.A456D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV66535768; called by muse, mutect2, varscan2
- POP1 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs148502433; called by muse, mutect2, varscan2
- PTHLH | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 65/245 reads (27%) | catalogued as COSV52366593; called by muse, mutect2, varscan2
- ROBO1 | c.272C>G p.A91G | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71391834; called by muse, mutect2, varscan2
- ROBO2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159415876, COSV59897359; called by muse, mutect2, varscan2
- RP1L1 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as rs779548004, COSV66751784, COSV66762181; called by muse, mutect2, varscan2
- RXFP2 | c.1751T>C p.I584T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV53633110; called by muse, mutect2, varscan2
- SCN3A | c.2391G>A p.L797= | Splice Region (SNP) | VAF 19/90 reads (21%) | catalogued as COSV51801616; called by muse, mutect2, varscan2
- SDK1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1277316900, COSV67356984; called by muse, mutect2, varscan2
- SEMA4B | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759611815, COSV60172317; called by muse, mutect2, varscan2
- SH3TC1 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as COSV55281362; called by muse, mutect2, varscan2
- SLITRK5 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100281297; called by muse, mutect2, varscan2
- SOS1 | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.429); catalogued as COSV67673868; called by muse, mutect2, varscan2
- SP3 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59466188; called by muse, mutect2, varscan2
- SPATS2L | c.194dup p.K66Efs*4 | Frame Shift Ins (INS) | VAF 45/153 reads (29%) | catalogued as rs1402792126; called by mutect2, pindel, varscan2
- SRD5A2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs372049682, COSV51871075; called by mutect2, varscan2
- TAZ | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375663114, CM022463, COSV54795849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM131L | c.1030T>G p.F344V | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53641183; called by muse, mutect2, varscan2
- TMEM151A | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100517088; called by muse, mutect2, varscan2
- TRIM37 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as COSV51881482; called by muse, mutect2, varscan2
- TUT4 | c.4912C>G p.P1638A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV99932912; called by muse, mutect2, varscan2
- UBAP2L | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1382591999, COSV55167856; called by muse, mutect2, varscan2
- UBE2A | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV60635974; called by muse, mutect2, varscan2
- USP51 | c.1297C>A p.H433N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV72351485; called by muse, varscan2
- ZC3H13 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 161/339 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.982); catalogued as COSV54447944, COSV99669012; called by muse, mutect2, varscan2
- ZDHHC1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs759312519, COSV62214563; called by muse, mutect2, varscan2
- ZNF157 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 100/143 reads (70%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.51); catalogued as rs1431635226, COSV65658434; called by muse, mutect2, varscan2
- ZNF257 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV71306223; called by muse, mutect2
- ZNF550 | c.778A>T p.K260* | Nonsense Mutation (SNP) | VAF 34/116 reads (29%) | catalogued as COSV57303584; called by muse, mutect2, varscan2
- ZNF75D | c.1086G>C p.E362D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV66132378; called by muse, mutect2, varscan2
- ZNF804B | c.1563A>C p.E521D | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV60816662; called by muse, mutect2, varscan2
- ZNFX1 | c.2609A>C p.D870A | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV100871031; called by muse, mutect2
- SH3BP1 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, varscan2
- SHMT2 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNFRSF13B | c.504dup p.L169Afs*68 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- ABR | c.81C>T p.D27= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs753890821, COSV56831925; called by muse, mutect2, varscan2
- ADAMTS12 | c.4278G>A p.A1426= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs149971505; called by muse, mutect2, varscan2
- AP1M1 | c.741C>T p.F247= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs142555840; called by muse, mutect2, varscan2
- ATAD5 | c.468T>C p.T156= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100430274; called by muse, mutect2, varscan2
- ATP2B2 | c.366C>T p.S122= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1390327917, COSV59489490; called by muse, mutect2, varscan2
- CNTRL | c.5094A>T p.L1698= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as COSV53043315; called by muse, mutect2
- COL4A4 | c.3021C>T p.Y1007= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs746105339, COSV61629602; called by muse, mutect2, varscan2
- CRB1 | c.2463G>A p.T821= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs375269970; called by muse, mutect2, varscan2
- CTNND2 | c.1164G>A p.P388= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV58865959, COSV58907954; called by muse, mutect2, varscan2
- CTSL | c.120C>T p.Y40= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs546059099, COSV58245705; called by muse, mutect2, varscan2
- DAPK1 | c.3840C>T p.S1280= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100802858; called by muse, mutect2, varscan2
- DLC1 | c.2058G>A p.A686= (on ENST00000276297 / NM_001348081.2; = p.A249= on NM_006094.5) | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs372344109; called by muse, mutect2, varscan2
- DPYSL4 | c.634T>C p.L212= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV58305946; called by muse, mutect2, varscan2
- DSCAML1 | c.2493C>T p.N831= (on ENST00000321322; = p.N771= on NM_020693.4) | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs775738418, COSV58381830; called by muse, mutect2, varscan2
- DTNB | c.33C>T p.T11= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV56473075; called by muse, mutect2, varscan2
- EMILIN2 | c.1128G>T p.L376= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99598798, COSV99599003; called by muse, mutect2
- FNDC8 | c.696A>C p.P232= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1206667825, COSV50100514; called by muse, mutect2
- GABRA5 | c.621C>T p.N207= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs200310381; called by muse, mutect2, varscan2
- GGN | c.27C>T p.S9= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV53055996; called by muse, mutect2, varscan2
- HRNR | c.1329G>T p.G443= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV64254340; called by muse, mutect2, varscan2
- ICE1 | c.1764A>G p.L588= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs374313250; called by muse, mutect2, varscan2
- ITK | c.585C>T p.N195= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as rs988688399, COSV70060429; called by muse, mutect2, varscan2
- LAMC3 | c.804C>T p.G268= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs139742340; called by mutect2, varscan2
- LILRB3 | c.1911C>T p.Y637= (on ENST00000346401; = p.Y625= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as rs771330822, COSV54429289; called by muse, mutect2, varscan2
- LRIG3 | c.2679A>G p.P893= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV57860914; called by muse, mutect2, varscan2
- MKX | c.246G>A p.A82= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs750137844, COSV65391489; called by muse, mutect2, varscan2
- MYL1 | c.283C>T p.L95= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV58974098; called by muse, mutect2, varscan2
- NLRX1 | c.1663C>T p.L555= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV52701499; called by muse, mutect2, varscan2
- NPBWR1 | c.72C>A p.S24= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100488331; called by muse, mutect2, varscan2
- PCDHA3 | c.1542C>T p.S514= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV63539417; called by muse, mutect2, varscan2
- PCDHGA12 | c.1323C>T p.N441= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs376415955; called by muse, mutect2, varscan2
- PCDHGB2 | c.855C>T p.D285= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1486053605, COSV53894909; called by muse, mutect2, varscan2
- PLCB2 | c.3369G>A p.A1123= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs767903110, COSV53030856; called by muse, mutect2, varscan2
- PLXNB3 | c.207C>A p.G69= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV62795457; called by muse, mutect2, varscan2
- PPP1R16A | c.729G>T p.G243= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV52952193; called by muse, mutect2, varscan2
- RTN2 | c.90C>T p.D30= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1446544548, COSV55592586; called by muse, mutect2, varscan2
- SCNN1B | c.1845C>T p.T615= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs760344381, COSV100226073; called by muse, mutect2, varscan2
- TECTA | c.5247C>T p.T1749= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs377599437; called by muse, mutect2, varscan2
- TMED7 | c.33G>A p.A11= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs750086396; called by muse, mutect2
- TRIP12 | c.4678C>A p.R1560= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV99391041; called by muse, mutect2
- USP49 | c.387G>A p.P129= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs745385844, COSV99790744; called by muse, mutect2, varscan2
- USP51 | c.1302G>C p.L434= | Silent (SNP) | VAF 64/89 reads (72%) | catalogued as COSV72351484; called by muse, varscan2
- VPS39 | c.561A>C p.L187= (on ENST00000348544 / NM_001301138.2; = p.L176= on NM_015289.5) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV58787815; called by muse, mutect2, varscan2
- ZBED9 | c.3300C>G p.A1100= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV101509413; called by muse, mutect2, varscan2
- ZFHX4 | c.966A>C p.I322= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as COSV51489625, COSV99268620; called by muse, mutect2, varscan2
- ZNF292 | c.492G>A p.P164= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs752923565, COSV100369952, COSV60535338; called by muse, mutect2, varscan2
- BRWD1 | c.6571+130G>A | Intron (SNP) | VAF 73/257 reads (28%) | catalogued as COSV60892767; called by muse, mutect2, varscan2
- MFRP | chr11:119344940 C>T | 5'Flank (SNP) | VAF 14/45 reads (31%) | catalogued as rs147276252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPS17P9 | n.316C>A | RNA (SNP) | VAF 97/189 reads (51%) | called by muse, mutect2, varscan2
- PIP4K2A | c.678+93G>A | Intron (SNP) | VAF 46/121 reads (38%) | catalogued as COSV100114727; called by muse, mutect2, varscan2
